Gene-level copy-number profile of tumor specimen TCGA-OR-A5LS-01A from TCGA case TCGA-OR-A5LS, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 34.7 years (12,663 days).
Specimen TCGA-OR-A5LS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.ff8cf96c-3447-4e79-bbc0-44a019bbf3ce.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5LS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/63ceacfe-90a2-461b-9fc7-9ee7744150f8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 1,394; copy number 2: 29,198; copy number 3: 1,524; copy number 4: 25,015; copy number 5: 393; copy number 6: 2,275; copy number 7: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5LS-01A-11D-A29H-01): tumor purity 0.84, ploidy 3.04, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:186,354,570–186,680,901, 5 genes (within-gene range 0–2): AC017071.1, MED28P3, ZC3H15, DPRXP1, ITGAV.
- chr3:4,414,580–4,847,840, 3 genes (within-gene range 0–2): MRPS10P2, ITPR1-DT, ITPR1.
- chr11:41,394,595–41,426,504, 1 gene: AC090138.1.
- chr11:41,538,434–41,538,986, 1 gene: AC021006.1.
- chr13:91,994,518–92,180,885, 3 genes: AL162456.1, RNU4ATAC3P, FABP5P4.
- chr22:28,883,572–29,168,333, 7 genes (within-gene range 0–2): ZNRF3, ZNRF3-IT1, ZNRF3-AS1, C22orf31, KREMEN1, AL021393.1, RNU6-810P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,669 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:50,396,192–181,342,213, 2,275 genes, copy number 6 (broad region; genes not listed).
- chr10:44,591,208–44,602,104, 1 gene, copy number 7: AL356157.1.
- chr14:22,066,016–22,495,966, 57 genes, copy number 5: AC245505.3, TRAV22, TRAV23DV6, TRDV1, TRAV24, TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43.
- chr19:54,155,161–58,605,223, 336 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,394. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
